Somatic mutation profile of tumor specimen 0DUNQ0 from CCDI case PBCLPG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Pelvis, NOS; Age at diagnosis: 2.9 years (1,057 days).
Specimen 0DUNQ0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0bf54cf0-e36c-4e14-907f-3fcdfb2d4fa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUNP4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a1f86b6-df20-4582-9bb9-344cc3a6ef8e

The open-access MAF lists 22 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 3, 5'UTR 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FAM47C | c.1085G>A p.R362H | Missense Mutation (SNP) | VAF 98/390 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs149671724, COSV63725620; called by muse, varscan2
- FMNL3 | c.1841C>T p.A614V | Missense Mutation (SNP) | VAF 156/540 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1450115229, COSV53300028; called by muse, mutect2, varscan2
- FNBP1L | c.1384C>G p.R462G (on ENST00000271234 / NM_001164473.2; = p.R404G on NM_017737.5) | Missense Mutation (SNP) | VAF 168/408 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99554154; called by muse, mutect2, varscan2
- RFNG | c.174C>G p.D58E | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as rs1015473605; called by muse, mutect2, varscan2
- UTP25 | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 53/676 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs141651647; called by muse, mutect2
- EXOC3L4 | c.98G>T p.S33I | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GRIPAP1 | c.1218A>C p.Q406H | Missense Mutation (SNP) | VAF 98/434 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PAK6 | c.1360G>C p.V454L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- TMPRSS15 | c.1593G>C p.W531C | Missense Mutation (SNP) | VAF 90/298 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, varscan2
- TRIM66 | c.1022T>C p.I341T | Missense Mutation (SNP) | VAF 97/340 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- VPS13B | c.10093G>T p.A3365S | Missense Mutation (SNP) | VAF 60/688 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.265); called by muse, mutect2
- ATP11C | c.885G>A p.L295= | Silent (SNP) | VAF 41/623 reads (7%) | called by muse, mutect2
- ENG | c.1542C>A p.G514= | Silent (SNP) | VAF 74/176 reads (42%) | called by mutect2, varscan2
- FAM171A2 | c.708C>T p.P236= | Silent (SNP) | VAF 18/437 reads (4%) | catalogued as rs1332811131; called by muse, mutect2
- NOBOX | c.345G>T p.L115= | Silent (SNP) | VAF 92/279 reads (33%) | called by muse, mutect2, varscan2
- NRG1 | c.922C>T p.L308= (on ENST00000405005 / NM_013964.5; = p.L313= on NM_013956.5) | Silent (SNP) | VAF 85/253 reads (34%) | called by muse, mutect2, varscan2
- ACTA2 | c.617-77A>T | Intron (SNP) | VAF 7/61 reads (11%) | called by muse, mutect2, varscan2
- HTR7 | c.-37G>T | 5'UTR (SNP) | VAF 28/91 reads (31%) | catalogued as rs12762898; called by muse, mutect2, varscan2
- MATN2 | c.1327+72C>A | Intron (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- MUC2 | chr11:1096176 C>A | 3'Flank (SNP) | VAF 55/253 reads (22%) | called by muse, mutect2, varscan2
- PELATON | n.198-55A>T | Intron (SNP) | VAF 55/128 reads (43%) | called by muse, mutect2, varscan2
- SNAI1 | c.-7G>A | 5'UTR (SNP) | VAF 154/326 reads (47%) | called by muse, mutect2, varscan2
